Somatic mutation profile of tumor specimen C3N-02765-02 (aliquot CPT0184450055) from CPTAC case C3N-02765, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.0 years (28,127 days).
Specimen C3N-02765-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fec35e7-f950-4eb8-a641-01083d5a3a5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02765-71 (Blood Derived Normal), aliquot CPT0184500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/badd1291-6396-4852-9d5d-6d6647256243

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Nonsense Mutation 4, RNA 3, Splice Region 3, Splice Site 2, 5'UTR 2, 5'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 31/301 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs199677222, COSV65450811; called by muse, mutect2
- ARMC6 | c.1240G>A p.A414T (on ENST00000392336; = p.A389T on NM_033415.4) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs1450184852; called by muse, mutect2
- BRINP3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755315472; called by muse, mutect2, varscan2
- FLT4 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs744282; called by muse, mutect2, varscan2
- GLIPR1L1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs146026558; called by muse, mutect2, varscan2
- H4C3 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV100619624; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 44/1044 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs1310285297; called by muse, mutect2
- ISX | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758150909, COSV100434055; called by muse, mutect2, varscan2
- ITPKC | c.1397C>A p.T466N | Missense Mutation (SNP) | VAF 64/520 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1231873309; called by muse, mutect2, varscan2
- KAT8 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54896209; called by muse, mutect2, varscan2
- KIF26B | c.5237G>A p.R1746H | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63647981; called by muse, mutect2, varscan2
- MAGEL2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as rs958433254; called by muse, mutect2, varscan2
- OR5T3 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1406535307; called by muse, mutect2, varscan2
- OR7E24 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 37/249 reads (15%) | catalogued as rs758705081; called by muse, mutect2, varscan2
- PCDHB5 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 124/1006 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV50655031; called by muse, varscan2
- PITRM1 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 27/203 reads (13%) | catalogued as rs767127875, COSV56530019; called by muse, mutect2, varscan2
- RNF213 | c.8770G>A p.V2924I | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs776483860, COSV60413128; called by muse, mutect2, varscan2
- ROR1 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283520472; called by muse, mutect2, varscan2
- SMAD4 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 12/287 reads (4%) | catalogued as COSV61687522; called by muse, mutect2
- SYT10 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1242285420, COSV57339451; called by muse, mutect2, varscan2
- TP53 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV53055641, COSV53176708, COSV53268129; called by muse, mutect2, varscan2
- TPR | c.1724+1G>T p.X575_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | catalogued as COSV100823742; called by muse, mutect2, varscan2
- TSPEAR | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs1425457705, COSV59957782, COSV59960387; called by muse, mutect2, varscan2
- VWC2 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1428418971, COSV61482544; called by muse, mutect2, varscan2
- GK | c.1502-6T>A | Splice Region (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- MACF1 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- MON2 | c.3199G>A p.V1067I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); called by muse, mutect2
- NFKBIZ | c.502_505del p.P168Ifs*20 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- NIPBL | c.6306T>G p.N2102K | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRAMEF2 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PVR | c.990A>G p.K330= | Splice Region (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- SGK1 | c.418-17_435del p.X140_splice | Splice Site (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- STARD3NL | c.382-5T>C | Splice Region (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- ATXN1L | c.1696C>T p.L566= | Silent (SNP) | VAF 25/180 reads (14%) | catalogued as rs1225317677; called by muse, mutect2, varscan2
- GRM3 | c.2109G>T p.V703= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs749899084; called by muse, mutect2, varscan2
- HECTD4 | c.7671G>A p.A2557= | Silent (SNP) | VAF 36/272 reads (13%) | catalogued as rs765807587, COSV101108443; called by muse, mutect2, varscan2
- IQCE | c.687G>A p.K229= | Silent (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- MMP16 | c.1200C>T p.D400= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs749625537, COSV54149139, COSV54180953; called by muse, mutect2
- SGSM3 | c.1653G>A p.S551= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs775450044, COSV99960580; called by muse, mutect2, varscan2
- AGAP12P | n.1944T>C | RNA (SNP) | VAF 118/1792 reads (7%) | called by muse, mutect2
- AQP12A | chr2:240688418 C>T | 5'Flank (SNP) | VAF 27/208 reads (13%) | catalogued as rs896642495; called by muse, mutect2, varscan2
- FBXL21P | n.864G>A | RNA (SNP) | VAF 25/128 reads (20%) | catalogued as rs191830002, COSV99778188; called by muse, mutect2, varscan2
- HRH3 | c.*635G>T | 3'UTR (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- PACS2 | c.-1C>A | 5'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as rs1218165671; called by muse, mutect2
- POLR3A | c.-36C>T | 5'UTR (SNP) | VAF 64/445 reads (14%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.611C>T | RNA (SNP) | VAF 18/86 reads (21%) | catalogued as rs1283370015; called by muse, mutect2, varscan2
